Gene-level copy-number profile of tumor specimen TCGA-KD-A5QU-01A from TCGA case TCGA-KD-A5QU, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 41.1 years (15,018 days).
Specimen TCGA-KD-A5QU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.a9835890-6a8d-4851-bc48-7abd4f254bbf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KD-A5QU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4039c819-9b41-4e48-8dcd-d4a35125ea34

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 578; copy number 2: 17,943; copy number 3: 16,185; copy number 4: 16,870; copy number 5: 7,517; copy number 6: 286; copy number 7: 372; copy number 8: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KD-A5QU-01A-11D-A27O-01): tumor purity 0.93, ploidy 1.5, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:42,255,873–42,256,575, 1 gene: FHP1.
- chr13:42,339,188–42,485,956, 1 gene (within-gene range 0–2): LINC02341.
- chr13:42,562,736–42,608,013, 1 gene (within-gene range 0–2): TNFSF11.
- chr13:49,956,670–50,906,856, 20 genes (within-gene range 0–2): DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1.
- chr13:89,833,157–90,926,597, 11 genes: RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,134 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,360,579–121,580,524, 2,207 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:98,087,173–120,349,354, 330 genes, copy number 5 (broad region; genes not listed).
- chr6:158,168,350–170,738,536, 234 genes, copy number 6 (broad region; genes not listed).
- chr8:36,121,398–145,066,685, 1,720 genes, copy number 5–7 (broad region; genes not listed).
- chr10:3,809,835–7,118,469, 81 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr10:13,057,902–19,790,401, 108 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:126,510,910–133,214,832, 208 genes, copy number 5 (broad region; genes not listed).
- chr16:11,555–5,235,822, 400 genes, copy number 5 (broad region; genes not listed).
- chr16:5,260,686–5,632,566, 6 genes, copy number 5: AC074051.2, RPS3AP48, SNRPCP20, NPM1P3, LINC01570, MIR8065.
- chr17:7,686,071–16,218,185, 225 genes, copy number 5 (broad region; genes not listed).
- chr17:51,153,559–52,160,017, 14 genes, copy number 5 (within-gene range 3–5): NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1.
- chr17:63,009,556–73,312,005, 238 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:5,830,408–24,163,425, 982 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:30,278,906–34,698,790, 145 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:42,072,752–46,308,498, 135 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:20,602,595–50,475,035, 1,101 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 578. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
